Somatic mutation profile of tumor specimen TCGA-AA-3869-01A (aliquot TCGA-AA-3869-01A-01W-0995-10) from TCGA case TCGA-AA-3869, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.8 years (28,062 days).
Specimen TCGA-AA-3869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ef62d01-202a-4054-a2a2-90f4cf2f1e76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3869-10A (Blood Derived Normal), aliquot TCGA-AA-3869-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82f51d8-f1cc-4864-bf07-6d5c6d97cd0c

The open-access MAF lists 81 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 282/321 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs397514456, CM030882, CM078353, COSV55681751; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 14/19 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC018630.4 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 34/183 reads (19%) | catalogued as rs200314617, COSV57392333; called by muse, mutect2, varscan2
- ADGRB1 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as rs781228120, COSV60093990; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>T p.A939V (on ENST00000506720 / NM_001322402.2; = p.A871V on NM_015236.6) | Missense Mutation (SNP) | VAF 272/1157 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs777017067, COSV101546801, COSV72230433; called by muse, mutect2, varscan2
- AFF1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.372); catalogued as COSV57121901; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 21/25 reads (84%) | catalogued as COSV57659668; called by muse, mutect2, varscan2
- APC | c.2696_2697del p.T899Ifs*12 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as COSV57362048, COSV57382541; called by mutect2, varscan2
- ATCAY | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1057024264; called by muse, mutect2, varscan2
- BCOR | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs778129253, COSV60719250; called by muse, mutect2, varscan2
- BUB1B | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55014630; called by muse, mutect2
- CCDC93 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 275/531 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV60122603; called by muse, mutect2, varscan2
- CENPN | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as rs753087047, COSV55143248; called by muse, mutect2, varscan2
- CFAP299 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs150179610, COSV63880172; called by muse, mutect2, varscan2
- CFAP58 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs147314126, COSV63834557; called by muse, mutect2, varscan2
- CLEC4C | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as rs768616751, COSV63582715; called by muse, mutect2, varscan2
- COL16A1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs41263975; called by muse, mutect2, varscan2
- CYP11B2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs377560888, CM087151; called by muse, mutect2, varscan2
- CYP7B1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs114067006; called by muse, mutect2, varscan2
- DCAF4L1 | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as rs765716567; called by muse, mutect2, varscan2
- DMXL2 | c.3188G>A p.S1063N | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1466963700, COSV51845230; called by muse, mutect2, varscan2
- ELOVL4 | c.760T>A p.Y254N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63954286; called by muse, mutect2, varscan2
- EPHA3 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs772463834, COSV60692526; called by muse, mutect2, varscan2
- FAM162B | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63920526; called by muse, mutect2, varscan2
- GPRASP1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as rs1247176633; called by muse, mutect2, varscan2
- GSK3A | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 50/119 reads (42%) | catalogued as COSV99725358; called by muse, mutect2, varscan2
- HLA-DQA2 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474270975, COSV66566033; called by muse, varscan2
- ITIH6 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs755854059, COSV54490819; called by muse, mutect2, varscan2
- KMT2C | c.13577A>G p.Y4526C | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777449616, COSV51432981; called by muse, mutect2, varscan2
- LCE1B | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1350549314, COSV63980468; called by muse, mutect2, varscan2
- MGAM | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761301600, COSV72075702; called by mutect2, varscan2
- NCAPD3 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759175654; called by muse, mutect2, varscan2
- NMUR2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV54920982; called by muse, mutect2
- NOL4 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866532141, COSV52342529; called by muse, mutect2, varscan2
- PIBF1 | c.1503A>C p.E501D | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV58325585; called by muse, varscan2
- PTPRG | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 115/226 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs764140516, COSV55650697, COSV55660767; called by muse, mutect2, varscan2
- RNF169 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777393692; called by mutect2, varscan2
- RPL32 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs200198457; called by muse, mutect2
- SAE1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV54296964; called by muse, mutect2, varscan2
- SCN4A | c.4963A>T p.K1655* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as rs1555600642; called by muse, mutect2, varscan2
- SHANK3 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1443347983, COSV53188868, COSV53192053; called by mutect2, varscan2
- SLC30A8 | c.1091G>T p.C364F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69973528; called by muse, mutect2, varscan2
- TNN | c.1376C>A p.A459E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs1390018611, COSV53430431; called by muse, mutect2, varscan2
- TTN | c.46436G>A p.R15479H (on ENST00000591111; = p.R8055H on NM_003319.4) | Missense Mutation (SNP) | VAF 59/124 reads (48%) | PolyPhen probably damaging (0.998); catalogued as rs778885931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UFL1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs776209390; called by muse, mutect2
- UNC45A | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67817476; called by muse, mutect2, varscan2
- VPS13A | c.7115A>G p.N2372S | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs1212235073, COSV100653417; called by muse, mutect2
- AURKC | c.759+2T>C p.X253_splice (on ENST00000302804 / NM_001015878.2; = p.X219_splice on NM_003160.3) | Splice Site (SNP) | VAF 21/63 reads (33%) | called by muse, varscan2
- EEPD1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM214A | c.2161A>C p.N721H | Missense Mutation (SNP) | VAF 119/243 reads (49%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- MAP1B | c.2610_2611del p.E871Afs*22 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- NCKAP5 | c.4037C>T p.S1346F | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIBF1 | c.1639+1G>T p.X547_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- PRPF4B | c.1238+2T>C p.X413_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SH3PXD2B | c.1936C>A p.P646T | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA31E1 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- SYCP2 | c.2831G>A p.C944Y | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM164 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ABCG4 | c.279C>T p.C93= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV56644692; called by muse, mutect2, varscan2
- ATG9B | c.762G>A p.P254= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as rs780844125, COSV65057828, COSV65058710; called by muse, mutect2, varscan2
- DDX19B | c.1116G>A p.R372= | Silent (SNP) | VAF 75/186 reads (40%) | catalogued as COSV99849896; called by muse, mutect2, varscan2
- EEPD1 | c.168G>A p.V56= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, varscan2
- EEPD1 | c.234G>A p.E78= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- MAP3K15 | c.3204G>A p.A1068= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs777381294, COSV58834208; called by muse, mutect2, varscan2
- NT5C1B | c.981C>T p.Y327= (on ENST00000359846 / NM_001199086.2; = p.Y267= on NM_033253.4) | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs376326986, COSV100409927; called by muse, mutect2, varscan2
- NUP42 | c.1035T>C p.F345= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs767521762; called by mutect2, varscan2
- PCDHA13 | c.930C>T p.F310= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56498969; called by muse, mutect2, varscan2
- PPM1L | c.627C>T p.N209= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as rs775202341, COSV55567177; called by muse, mutect2, varscan2
- PTPN1 | c.1263C>T p.A421= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs566921306, COSV50394999; called by muse, mutect2, varscan2
- PTPRT | c.1848C>T p.S616= | Silent (SNP) | VAF 319/466 reads (68%) | catalogued as COSV61998552; called by muse, mutect2, varscan2
- RAB23 | c.552G>A p.T184= | Silent (SNP) | VAF 316/983 reads (32%) | catalogued as rs201731610; called by muse, mutect2, varscan2
- RORB | c.1050G>C p.V350= (on ENST00000396204 / NM_001365023.1; = p.V339= on NM_006914.4) | Silent (SNP) | VAF 39/387 reads (10%) | catalogued as COSV65336024, COSV65338022; called by muse, mutect2, varscan2
- RYR1 | c.5352C>T p.A1784= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs373382967, COSV62103437; called by muse, mutect2, varscan2
- SLC2A10 | c.1593G>A p.P531= | Silent (SNP) | VAF 44/239 reads (18%) | catalogued as rs148424607; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SLITRK5 | c.2610C>T p.A870= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV61524395; called by muse, varscan2
- STAC2 | c.57C>T p.P19= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- TECTA | c.2643C>T p.F881= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs544376595, COSV50748360; ClinVar: uncertain significance; called by muse, mutect2
- TMEM164 | c.360C>T p.L120= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs752989031; called by muse, mutect2
- WDR47 | c.804T>C p.H268= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- MAT2B | chr5:163503406 G>T | 5'Flank (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55201429; called by muse, mutect2, varscan2
